TCGA case TCGA-BC-A10Q — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dfa15fbe-bb14-40ce-afc6-70694112e3e2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 1,135 days (3.1 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 72.3 years (26,400 days); Year of diagnosis: 1998; AJCC staging edition: 5th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 217 days; Embolic agent: PVA Particles.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 217 days; Days to treatment end: 217 days; Number of cycles: 1; Treatment dose: 20 mg; Prescribed dose: 20; Prescribed dose units: mg; Route of administration: Intrahepatic.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Mitomycin; Treatment intent type: Adjuvant; Days to treatment start: 217 days; Days to treatment end: 217 days; Number of cycles: 1; Treatment dose: 5 mg; Prescribed dose: 5; Prescribed dose units: mg; Route of administration: Intrahepatic.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 359 days; Days to treatment end: 408 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 426 days (1.2 years); Days to treatment end: 751 days (2.1 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS). Age at diagnosis: 73.2 years (26,740 days); Days to diagnosis: 340 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 340 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to recurrence: 340 days.
- Days to follow up: 1,135 days (3.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Albumin 4.1 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Creatinine 0.6 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.1].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9.
- Total Bilirubin 0.5 mg/dL.
- Platelets 287000 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 440].

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A10Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 340 mg.
  Slide TCGA-BC-A10Q-01A-01-BS1: Section location: Bottom; Percent tumor cells: 97; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 3; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BC-A10Q-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BC-A10Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A10Q-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 340 mg.
  Slide TCGA-BC-A10Q-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Extended Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: adriamycin.
- Drug treatment 1, Route of administrations: Route of administration: IH.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Mitomycin C.
- Drug treatment 3: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 2; Therapy regimen: Progression.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation, Embolization treatments, Embolization treatment: Embolization therapy drug name: Doxorubicon and Mitomycin C.

GDC annotations on this case (curator notes; quoted as recorded):
- General: Case originally accepted in the liver study, but is not a hepatocellular. This is a Cholangiocarcinoma and will not be removed or change studies, but will be analyzed in the CHOL study and not in the LIHC study.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,135 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,135 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 340 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A10Q-01A-11D-A12Y-01): tumor purity 0.72, ploidy 4.17, whole-genome doublings 2.
